Somatic mutation profile of tumor specimen TARGET-40-NAAHBZ-01A (aliquot TARGET-40-NAAHBZ-01A-01D) from TARGET case TARGET-40-NAAHBZ, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 9.6 years (3,499 days).
Specimen TARGET-40-NAAHBZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25684758-85e4-41b0-a9ee-2f5cd54bb45d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAHBZ-10A (Blood Derived Normal), aliquot TARGET-40-NAAHBZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62bc0b7c-4ca3-47b3-95b5-98f7658341f9

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 9, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.841G>T p.D281Y | Missense Mutation (SNP) | VAF 80/145 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764146326, CD137626, CM076566, CM153816, COSV52671054, COSV52674651, COSV52678614; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CCDC39 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as rs1378646642, COSV56494844, COSV99869801; called by muse, mutect2, varscan2
- TTN | c.77834C>A p.S25945Y (on ENST00000591111; = p.S18521Y on NM_003319.4) | Missense Mutation (SNP) | VAF 99/357 reads (28%) | PolyPhen probably damaging (0.914); catalogued as COSV100625816; called by muse, mutect2, varscan2
- ASXL3 | c.5518C>T p.Q1840* | Nonsense Mutation (SNP) | VAF 30/262 reads (11%) | called by muse, mutect2, varscan2
- CSMD1 | c.7983A>T p.R2661S (on ENST00000520002; = p.R2660S on NM_033225.6) | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HMCN1 | c.8587G>T p.V2863F | Missense Mutation (SNP) | VAF 96/221 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- MYOM2 | c.42G>C p.R14S | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- OSBPL8 | c.2149G>T p.A717S | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- PKHD1L1 | c.3112C>A p.Q1038K | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHANK1 | c.2448G>C p.Q816H | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EPHA6 | c.1857C>A p.G619= | Silent (SNP) | VAF 42/123 reads (34%) | catalogued as rs1384478160; called by muse, mutect2, varscan2
- FER1L6 | c.5265T>G p.P1755= | Silent (SNP) | VAF 38/500 reads (8%) | called by muse, mutect2
